Somatic mutation profile of tumor specimen TCGA-44-6778-01A (aliquot TCGA-44-6778-01A-11D-1855-08) from TCGA case TCGA-44-6778, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.5 years (21,725 days).
Specimen TCGA-44-6778-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20f884c7-1ac3-426a-8a51-aa3988bbde02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-44-6778-10A (Blood Derived Normal), aliquot TCGA-44-6778-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b54e06a8-fda6-4b84-bc02-b05c3c21b27c

The open-access MAF lists 420 somatic variants for this specimen: 312 protein-altering or splice-affecting, 96 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 275, Silent 96, Nonsense Mutation 16, Frame Shift Del 11, RNA 6, Intron 4, Frame Shift Ins 4, Splice Region 3, Splice Site 3, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.328A>G p.M110V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50268404, COSV50278748; called by muse, mutect2, varscan2
- TP53 | c.694A>T p.I232F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52677046, COSV52701937, COSV52704131, COSV53187960; called by muse, mutect2, varscan2
- ABCD2 | c.2041G>A p.G681R | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58054526; called by muse, mutect2, varscan2
- ACAD11 | c.1121T>C p.V374A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV53900646; called by muse, mutect2, varscan2
- ACSM5 | c.1459G>T p.V487L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV59374320; called by muse, mutect2, varscan2
- ACTN2 | c.1497G>T p.K499N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.557); catalogued as COSV63977784; called by muse, mutect2, varscan2
- ADAM18 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs1563262687, COSV55853815; called by muse, mutect2, varscan2
- AFMID | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.536); catalogued as COSV59977340; called by muse, mutect2, varscan2
- AHNAK2 | c.14723G>A p.S4908N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs778276859, COSV60923052; called by muse, mutect2, varscan2
- AKAP6 | c.2808G>T p.Q936H | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV55229665; called by muse, mutect2, varscan2
- AL645922.1 | c.943A>C p.M315L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as COSV100191489; called by muse, mutect2, varscan2
- ANK1 | c.1775G>C p.G592A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV55893190; called by muse, mutect2
- ANK2 | c.8351G>T p.S2784I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.116); catalogued as COSV52183894; called by muse, mutect2, varscan2
- ANKRD17 | c.6875C>T p.P2292L | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.289); catalogued as COSV58226661; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1244T>A p.L415* | Nonsense Mutation (SNP) | VAF 14/217 reads (6%) | catalogued as COSV62007578; called by muse, mutect2
- ANKRD35 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.872); catalogued as rs1553740712, COSV62911396; called by muse, mutect2, varscan2
- AP1M1 | c.882G>C p.M294I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV52228562; called by muse, mutect2
- AP1M2 | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV99141064; called by muse, mutect2, varscan2
- APCS | c.299C>T p.T100I | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99661520; called by muse, mutect2, varscan2
- ARHGAP21 | c.243+1G>T p.X81_splice | Splice Site (SNP) | VAF 11/47 reads (23%) | catalogued as COSV100903714; called by muse, mutect2, varscan2
- ARHGAP21 | c.243G>T p.K81N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100903715; called by muse, mutect2, varscan2
- ARID4A | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV62166205; called by muse, mutect2, varscan2
- ASH1L | c.6932G>T p.R2311L (on ENST00000368346 / NM_001366177.2; = p.R2306L on NM_018489.3) | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV64212773; called by muse, mutect2, varscan2
- BAHCC1 | c.5557G>T p.V1853L | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV57032444; called by muse, mutect2, varscan2
- BAZ1A | c.1888A>T p.T630S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.28); catalogued as COSV62411941; called by muse, mutect2, varscan2
- BEND7 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100347056; called by muse, mutect2, varscan2
- BTN3A2 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 83/166 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0.19); catalogued as rs780468088, COSV62688189; called by muse, mutect2, varscan2
- CACNA2D3 | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55574289; called by muse, mutect2, varscan2
- CCDC141 | c.4309G>T p.E1437* | Nonsense Mutation (SNP) | VAF 17/78 reads (22%) | catalogued as COSV99836821, COSV99837489; called by muse, mutect2, varscan2
- CD226 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs148019790; called by muse, mutect2, varscan2
- CD226 | c.615C>A p.S205R | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV54615371, COSV99711517; called by muse, mutect2, varscan2
- CD86 | c.193C>A p.L65M (on ENST00000330540 / NM_175862.5; = p.L59M on NM_006889.4) | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52609790; called by muse, mutect2, varscan2
- CDH10 | c.2187del p.Y730Tfs*19 | Frame Shift Del (DEL) | VAF 22/166 reads (13%) | catalogued as rs1273877423; called by mutect2, pindel, varscan2
- CDH12 | c.1904T>A p.V635E | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV66409381, COSV66441236; called by muse, mutect2, varscan2
- CEP162 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV57623503; called by muse, mutect2, varscan2
- CES2 | c.12C>A p.H4Q | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV57697654; called by muse, mutect2, varscan2
- CES3 | c.1606G>C p.G536R | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs149091298, COSV57595142; called by muse, mutect2, varscan2
- CFAP77 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100546137; called by muse, mutect2, varscan2
- CFAP91 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56341614, COSV56344122; called by muse, mutect2, varscan2
- CFHR5 | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as COSV56821819, COSV56827323; called by muse, mutect2, varscan2
- CHML | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as rs1266632076, COSV59366946; called by muse, mutect2, varscan2
- CHRM3 | c.1465G>T p.A489S | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55101101; called by muse, mutect2, varscan2
- CHRNA2 | c.1164G>T p.E388D | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV53559385; called by muse, mutect2, varscan2
- CHST3 | c.194C>G p.T65S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.027); catalogued as COSV64151645; called by muse, mutect2, varscan2
- CLU | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV57068118; called by muse, mutect2, varscan2
- CNTNAP2 | c.3987G>T p.W1329C | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV62243953; called by muse, mutect2, varscan2
- COL1A1 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV56808850; called by muse, mutect2, varscan2
- CPA6 | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV52740849; called by muse, mutect2, varscan2
- CPNE7 | c.1622C>G p.S541C | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52016156; called by muse, mutect2, varscan2
- CPOX | c.945T>G p.F315L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV51639561; called by muse, mutect2, varscan2
- CPXCR1 | c.888C>G p.C296W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52164297; called by muse, mutect2, varscan2
- CSMD3 | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV52113207; called by muse, mutect2, varscan2
- CTAGE1 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 81/327 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV66944518; called by muse, mutect2, varscan2
- CTTN | c.1474G>T p.D492Y | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV57233555, COSV57235586; called by muse, mutect2, varscan2
- CUBN | c.5983G>T p.G1995C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64715880; called by muse, mutect2, varscan2
- CUEDC1 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV64227160; called by muse, mutect2, varscan2
- CYP4F3 | c.133T>A p.C45S | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55413177; called by muse, mutect2, varscan2
- DCDC1 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV60856033; called by muse, mutect2, varscan2
- DCX | c.932G>T p.G311V (on ENST00000636035 / NM_001195553.2; = p.X311_splice on NM_000555.3) | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV57568945, COSV57574514; called by muse, mutect2, varscan2
- DHX34 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.326); catalogued as rs747233116, COSV60897788; called by muse, mutect2, varscan2
- DLC1 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as COSV52324108; called by muse, mutect2, varscan2
- DNAH2 | c.7368C>A p.S2456R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV66725463; called by muse, mutect2, varscan2
- DOCK2 | c.3200G>C p.G1067A | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV56944284, COSV56982960; called by muse, mutect2, varscan2
- DPP6 | c.1219A>G p.I407V (on ENST00000377770 / NM_001364500.2; = p.I345V on NM_001936.5) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.131); catalogued as COSV100128082; called by muse, mutect2, varscan2
- EHBP1 | c.2842G>T p.D948Y | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762554096, COSV50433839; called by muse, mutect2, varscan2
- EIF4H | c.10T>G p.F4V | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV56083210; called by muse, mutect2, varscan2
- ENTPD7 | c.1718G>A p.R573H | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs61738520, COSV65113138; called by muse, mutect2, varscan2
- EPHA6 | c.1597G>T p.D533Y | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV67586131, COSV67590472; called by muse, mutect2, varscan2
- EPHB6 | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as rs767628990, COSV67420532; called by muse, mutect2, varscan2
- ERBB4 | c.1872G>T p.G624= | Splice Region (SNP) | VAF 34/139 reads (24%) | catalogued as COSV53577651; called by muse, mutect2, varscan2
- ETV5 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60505937; called by muse, mutect2, varscan2
- EXPH5 | c.2945G>T p.C982F | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.631); catalogued as COSV56206825, COSV56207392; called by muse, mutect2, varscan2
- F8 | c.3461A>G p.E1154G | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV64277850; called by muse, mutect2, varscan2
- FAM135B | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 41/134 reads (31%) | catalogued as COSV52705894, COSV52749033; called by muse, mutect2
- FAT3 | c.8846G>T p.W2949L | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV53163482; called by muse, mutect2, varscan2
- FBN2 | c.400A>T p.S134C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV99330660; called by muse, mutect2, varscan2
- FBN2 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV52540488; called by muse, mutect2, varscan2
- FCGR2A | c.791G>T p.R264L (on ENST00000271450 / NM_001136219.3; = p.R263L on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV54840376; called by muse, varscan2
- FDX1 | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV52799643, COSV99501932; called by muse, mutect2, varscan2
- FDX1 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 35/139 reads (25%) | catalogued as COSV99501935; called by muse, mutect2, varscan2
- FGB | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 27/103 reads (26%) | catalogued as COSV57419377; called by muse, mutect2, varscan2
- FIBIN | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.47); catalogued as COSV100590530; called by muse, mutect2, varscan2
- FMO4 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63001845; called by muse, mutect2, varscan2
- FNDC5 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | catalogued as COSV100992541; called by muse, mutect2, varscan2
- FOXD4L1 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV52076306; called by muse, mutect2, varscan2
- FOXG1 | c.1287del p.S430Afs*5 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as COSV57398065; called by mutect2, pindel, varscan2
- FSCB | c.2181G>T p.E727D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV61219317, COSV61219348; called by muse, mutect2, varscan2
- GALNT17 | c.1694C>A p.T565K | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61186018, COSV61195738; called by muse, mutect2, varscan2
- GAS2L3 | c.349G>T p.G117C | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57158830; called by muse, mutect2, varscan2
- GIPC2 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1434702918, COSV66129294; called by muse, mutect2, varscan2
- GJD4 | c.17T>C p.L6S | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV58703279; called by muse, mutect2, varscan2
- GLB1L2 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60280367; called by muse, mutect2, varscan2
- GLP2R | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV52328883; called by muse, mutect2, varscan2
- GPR139 | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV58504692; called by muse, mutect2, varscan2
- GPR21 | c.708T>A p.S236R | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.085); catalogued as COSV65379178; called by muse, mutect2, varscan2
- GPRC5B | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV56028435; called by muse, mutect2, varscan2
- GRAMD1B | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV59209755; called by muse, mutect2
- GRIK2 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV59744412, COSV59764517; called by muse, mutect2, varscan2
- GRM3 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.684); catalogued as rs760648963, COSV64475392; called by muse, mutect2, varscan2
- H3-3B | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.023); catalogued as COSV54666824; called by muse, mutect2, varscan2
- HAPLN4 | c.253A>T p.K85* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV52271054; called by muse, mutect2, varscan2
- HCN4 | c.2540C>A p.S847Y | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV56086753; called by muse, mutect2, varscan2
- HECW1 | c.1085C>A p.A362D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.368); catalogued as COSV67838456; called by muse, mutect2
- HEPHL1 | c.1623C>A p.F541L | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV59895661; called by muse, mutect2, varscan2
- HMCN1 | c.10153C>T p.L3385F | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV54934256; called by muse, mutect2, varscan2
- HRH1 | c.1038A>G p.I346M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV67955908; called by muse, mutect2, varscan2
- HUNK | c.1064T>A p.L355Q | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54233583; called by muse, mutect2, varscan2
- IFNA16 | c.374A>T p.Q125L | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as COSV101207087; called by muse, mutect2, varscan2
- IFT88 | c.1789G>T p.V597F (on ENST00000319980 / NM_001318493.2; = p.V588F on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV60676682; called by muse, mutect2, varscan2
- IGSF9B | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58071910; called by muse, mutect2, varscan2
- IL5RA | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV56526103; called by muse, mutect2, varscan2
- INSRR | c.2029G>A p.G677R | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV63876747; called by muse, mutect2, varscan2
- INTS1 | c.3980G>T p.S1327I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs1562493801, COSV67179382; called by muse, mutect2
- ITGB8 | c.2137A>T p.S713C | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as COSV56013410; called by muse, mutect2, varscan2
- ITIH2 | c.2524C>G p.L842V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64431949; called by muse, mutect2, varscan2
- JMJD1C | c.2761A>T p.S921C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV59517518; called by muse, mutect2
- KANK4 | c.2845C>A p.L949M | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100443335; called by muse, mutect2, varscan2
- KCNA7 | c.1334G>T p.W445L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.021); catalogued as COSV99672033; called by muse, mutect2, varscan2
- KHDC3L | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745893907, COSV64869684; called by muse, mutect2, varscan2
- KLHL31 | c.1060A>C p.K354Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV63882316; called by muse, mutect2
- KRTAP13-2 | c.402C>A p.S134R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV67762230, COSV67762264; called by muse, mutect2
- KRTAP13-4 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV61879356, COSV61880145; called by muse, mutect2, varscan2
- KRTAP19-7 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.031); catalogued as rs1233341196, COSV58366507; called by muse, mutect2, varscan2
- LEXM | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1447491950, COSV64024022; called by muse, mutect2, varscan2
- LIN28B | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.59); catalogued as COSV61497263; called by muse, mutect2, varscan2
- LONRF1 | c.1723A>G p.M575V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as rs374041976; called by muse, mutect2, varscan2
- LRFN2 | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100599939; called by muse, mutect2, varscan2
- LRP4 | c.2565G>T p.W855C | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66138325; called by muse, mutect2, varscan2
- LRRTM4 | c.1214C>A p.S405Y | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as rs1386387121, COSV69141710; called by muse, mutect2, varscan2
- LRTM2 | c.1000A>T p.I334F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99766507; called by muse, mutect2, varscan2
- LTBP1 | c.3971C>T p.T1324I (on ENST00000404816 / NM_206943.4; = p.T998I on NM_000627.4) | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); catalogued as COSV55384463; called by muse, mutect2
- MAG | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | catalogued as COSV62702565; called by muse, mutect2
- MAGEF1 | c.821G>C p.R274P | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV58634264; called by muse, mutect2, varscan2
- MAP2K1 | c.767T>C p.M256T | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs1326401609, COSV61073106; called by muse, mutect2, varscan2
- MARCHF11 | c.1034G>C p.W345S | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV60133766; called by muse, mutect2, varscan2
- MARS2 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 78/432 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV56572262; called by muse, mutect2, varscan2
- MCMDC2 | c.273G>T p.Q91H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV58040142; called by mutect2, varscan2
- MED13 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV67266548; called by mutect2, varscan2
- MEOX1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV59357206; called by muse, mutect2, varscan2
- MFAP5 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV63946203; called by muse, mutect2, varscan2
- MGAT5B | c.589T>C p.F197L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV56935576; called by muse, mutect2
- MICALL1 | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV53243045; called by muse, mutect2, varscan2
- MIS18BP1 | c.745C>G p.Q249E | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.441); catalogued as rs185296509, COSV60373126; called by muse, mutect2
- MN1 | c.3032G>T p.G1011V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV100180152; called by muse, mutect2
- MOS | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100323029; called by muse, mutect2, varscan2
- MRPS10 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.949); catalogued as rs775790112, COSV50002485; called by muse, mutect2, varscan2
- MUC17 | c.7441G>T p.V2481F | Missense Mutation (SNP) | VAF 148/697 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV60300785; called by muse, mutect2, varscan2
- MUC3A | c.8882G>T p.G2961V | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.739); catalogued as rs1325635139, COSV60223610; called by muse, mutect2
- MUC7 | c.350C>A p.P117Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as COSV59219924; called by muse, mutect2, varscan2
- MYH1 | c.4656+1G>T p.X1552_splice | Splice Site (SNP) | VAF 17/94 reads (18%) | catalogued as rs1275822562, COSV56855715; called by muse, mutect2, varscan2
- MYH2 | c.3872G>T p.G1291V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747924610, COSV55446928; ClinVar: uncertain significance; called by muse, mutect2
- MYH4 | c.3021C>A p.H1007Q | Missense Mutation (SNP) | VAF 97/378 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.299); catalogued as COSV55112844; called by muse, mutect2, varscan2
- MYO18B | c.1095G>T p.L365F | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.061); catalogued as COSV59146042; called by muse, mutect2, varscan2
- MYO7B | c.417C>G p.N139K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV67351171; called by muse, mutect2, varscan2
- MYOM3 | c.1226T>C p.I409T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV58399911; called by muse, mutect2, varscan2
- MYOZ2 | c.558C>G p.N186K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61086011; called by muse, mutect2, varscan2
- NBAS | c.7096G>C p.A2366P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as rs778106322, COSV55720017, COSV55735431; called by muse, mutect2, varscan2
- NCKAP5L | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs745826212, COSV60133079; called by muse, mutect2, varscan2
- NDUFS1 | c.1826C>A p.A609E | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51913057; called by muse, mutect2, varscan2
- NEUROD1 | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); catalogued as COSV99717054; called by muse, mutect2, varscan2
- NLRP7 | c.2447C>A p.P816Q (on ENST00000340844 / NM_206828.3; = p.P788Q on NM_139176.3) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV60180865; called by muse, mutect2, varscan2
- NMUR1 | c.1172G>T p.R391M | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV59405566; called by muse, mutect2, varscan2
- NPAP1 | c.1693C>A p.L565I | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.159); catalogued as COSV61510533; called by muse, mutect2, varscan2
- NPFFR2 | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.233); catalogued as COSV58153566; called by muse, mutect2
- NRCAM | c.2120C>A p.A707D (on ENST00000379028 / NM_001371124.1; = p.A691D on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV61046975; called by muse, mutect2, varscan2
- NUP214 | c.5522-1G>T p.X1841_splice | Splice Site (SNP) | VAF 21/105 reads (20%) | catalogued as COSV63912624; called by muse, mutect2, varscan2
- NUP62 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV61313384; called by muse, mutect2, varscan2
- ODR4 | c.869A>G p.Y290C | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99834509; called by muse, mutect2, varscan2
- OGDHL | c.2570G>A p.S857N | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV65103669; called by muse, mutect2, varscan2
- OIT3 | c.456C>A p.D152E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV61827138; called by muse, mutect2, varscan2
- OR10A5 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.089); catalogued as COSV55055461; called by muse, mutect2, varscan2
- OR14C36 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV58602577; called by muse, mutect2, varscan2
- OR14I1 | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV100700492, COSV61200709; called by muse, mutect2, varscan2
- OR1Q1 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52917800, COSV52918919; called by muse, mutect2, varscan2
- OR2J2 | c.829C>A p.L277I | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV65848338; called by muse, mutect2, varscan2
- OR2T2 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100737800; called by muse, mutect2, varscan2
- OR2T27 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as COSV61283359; called by muse, mutect2, varscan2
- OR52N1 | c.271C>G p.L91V | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV100398624, COSV57693972; called by muse, mutect2
- OR56A4 | c.365C>A p.S122Y | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100417693; called by muse, mutect2, varscan2
- OR56B4 | c.801C>A p.H267Q | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs765306002, COSV57205409; called by muse, mutect2, varscan2
- OR5AN1 | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.372); catalogued as COSV100004472; called by muse, mutect2, varscan2
- OR5AS1 | c.587A>T p.Q196L | Missense Mutation (SNP) | VAF 81/450 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV57983015; called by muse, mutect2, varscan2
- OR5H6 | c.175C>A p.L59I (on ENST00000642105; = p.L43I on NM_001005479.2) | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as COSV67351013, COSV67352020; called by muse, mutect2, varscan2
- OR5K2 | c.53C>A p.T18K | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV71143470; called by muse, mutect2, varscan2
- OR5M10 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV73242428; called by muse, mutect2, varscan2
- ORC1 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234934732, COSV65365017; called by muse, mutect2, varscan2
- P2RY8 | c.926G>C p.G309A | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV67178077; called by muse, mutect2, varscan2
- PATE1 | c.209C>A p.T70K | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.398); catalogued as COSV59825305; called by muse, mutect2, varscan2
- PCDH11Y | c.2617C>A p.H873N (on ENST00000400457 / NM_032973.2; = p.H862N on NM_032971.3) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.348); catalogued as COSV53089657; called by muse, mutect2, varscan2
- PCDH15 | c.4790G>A p.S1597N (on ENST00000644397 / NM_001354429.2; = p.S1539N on NM_001142771.2) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as rs752635201, COSV100904643, COSV100905639; called by muse, mutect2, varscan2
- PCDHB2 | c.376A>T p.R126W | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99523580; called by muse, mutect2, varscan2
- PCDHGA4 | c.1972C>G p.R658G | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV53930460, COSV54016618; called by muse, mutect2, varscan2
- PCGF5 | c.130G>T p.V44F | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV60239169; called by muse, mutect2, varscan2
- PCLO | c.2645G>T p.R882L | Missense Mutation (SNP) | VAF 183/567 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as COSV61622674, COSV61660530; called by muse, mutect2, varscan2
- PCOLCE2 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as rs1452427497, COSV56001607; called by muse, mutect2, varscan2
- PEG3 | c.3860G>T p.C1287F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV55644895; called by muse, mutect2, varscan2
- PEG3 | c.1156A>G p.R386G | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV55644910; called by muse, mutect2, varscan2
- PGK2 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59165363; called by muse, mutect2
- PIK3C2G | c.2164C>A p.R722S (on ENST00000676171; = p.R681S on NM_004570.5) | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56823595, COSV56829183; called by muse, mutect2, varscan2
- PIK3CB | c.182A>C p.K61T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV56689467; called by muse, mutect2, varscan2
- PKHD1 | c.8753G>A p.G2918D | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs369668483; called by muse, mutect2, varscan2
- PKP4 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs199631736, COSV67676224; called by muse, mutect2, varscan2
- PLAT | c.964C>T p.H322Y | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54277617; called by muse, mutect2, varscan2
- PLCE1 | c.1558A>T p.K520* | Nonsense Mutation (SNP) | VAF 21/153 reads (14%) | catalogued as COSV53368200; called by muse, mutect2, varscan2
- PLCXD3 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV60616386; called by muse, mutect2, varscan2
- PNLIPRP3 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs770845391, COSV65049467; called by muse, mutect2, varscan2
- PPP2R5E | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV61743952; called by muse, mutect2, varscan2
- PPP6R3 | c.485T>C p.I162T | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV55734887; called by muse, mutect2, varscan2
- PPWD1 | c.1844G>C p.G615A | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51554131; called by muse, mutect2, varscan2
- PRSS55 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV60809214; called by muse, mutect2, varscan2
- PTCHD4 | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV59795202; called by muse, mutect2
- PTPRB | c.1545A>T p.K515N | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as COSV54251293; called by muse, mutect2
- PTPRK | c.3976G>A p.G1326S (on ENST00000368215 / NM_001291984.2; = p.G1327S on NM_002844.4) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV63898441; called by muse, mutect2
- PTPRT | c.3157C>A p.H1053N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV62012312; called by muse, mutect2, varscan2
- R3HCC1L | c.973G>C p.V325L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV54404780; called by muse, mutect2, varscan2
- RAB26 | c.656C>A p.T219K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV99270013; called by muse, mutect2, varscan2
- RELN | c.8346C>G p.F2782L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.772); catalogued as COSV58994193, COSV59029623; called by muse, mutect2, varscan2
- REV3L | c.5140T>C p.S1714P | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1163683183, COSV62622491, COSV62624382; called by muse, mutect2, varscan2
- RFPL1 | c.398C>G p.T133R | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62978511; called by muse, mutect2, varscan2
- RP1L1 | c.4361C>A p.P1454H | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs1356900260, COSV66759359; called by muse, mutect2, varscan2
- RPTN | c.1874G>T p.G625V | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV60168886; called by muse, mutect2, varscan2
- RRAGC | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs778865918, COSV65931987; called by muse, mutect2, varscan2
- RUFY2 | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV66253358; called by muse, mutect2, varscan2
- RUNX1T1 | c.1252C>A p.P418T (on ENST00000265814 / NM_001198628.1; = p.P391T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV56160726; called by muse, mutect2, varscan2
- RXFP1 | c.1466G>C p.G489A | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100313948, COSV57055290; called by muse, mutect2, varscan2
- RYR1 | c.165G>T p.Q55H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62108480; called by muse, mutect2, varscan2
- RYR1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1204636873, COSV62108489; called by muse, mutect2, varscan2
- RYR2 | c.3239G>T p.G1080V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63709110; called by muse, mutect2
- S100A7L2 | c.148A>T p.S50C | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV64195559; called by muse, mutect2, varscan2
- SCG3 | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 85/286 reads (30%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as COSV55022923; called by muse, mutect2, varscan2
- SCN2A | c.1954G>T p.G652C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51853286, COSV51858413; called by muse, mutect2, varscan2
- SCNN1B | c.253G>C p.V85L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV56304549, COSV56309339; called by muse, mutect2, varscan2
- SEMA5A | c.1027T>A p.S343T | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.206); catalogued as COSV66803682; called by muse, mutect2, varscan2
- SEMG1 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV54873614; called by muse, mutect2, varscan2
- SEMG1 | c.1018A>G p.S340G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.95); catalogued as rs56342547, COSV54874257; called by mutect2, varscan2
- SETX | c.5584C>G p.Q1862E | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV56393183; called by muse, mutect2, varscan2
- SFRP1 | c.860G>A p.W287* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as COSV55177000, COSV99617861; called by muse, mutect2, varscan2
- SH2D3C | c.152A>T p.E51V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs771568554, COSV59128770; called by muse, mutect2, varscan2
- SIGLEC1 | c.3441C>A p.Y1147* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV52471142; called by muse, mutect2, varscan2
- SIGLEC5 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55783005, COSV55783837; called by muse, mutect2, varscan2
- SLAMF1 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV52501681; called by muse, mutect2, varscan2
- SLC14A2 | c.62A>T p.Y21F | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.225); catalogued as COSV54910991, COSV54913836; called by muse, mutect2, varscan2
- SLC17A3 | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 7/85 reads (8%) | catalogued as COSV100399332; called by muse, mutect2
- SLC17A6 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.201); catalogued as rs138598101, COSV99580955; called by muse, mutect2, varscan2
- SLC17A6 | c.963C>A p.C321* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as COSV54140454; called by muse, mutect2, varscan2
- SLC26A4 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); catalogued as rs1360614366, COSV55919501; called by muse, mutect2, varscan2
- SLC39A6 | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV52371075; called by muse, mutect2, varscan2
- SLC8A2 | c.2242G>A p.G748S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52639792; called by muse, mutect2, varscan2
- SMC3 | c.2626A>C p.T876P | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.61); catalogued as COSV62422029; called by muse, mutect2, varscan2
- SMYD2 | c.179A>G p.E60G | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.701); catalogued as COSV65291649; called by muse, mutect2, varscan2
- SOX5 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.889); catalogued as rs778593487, COSV58645781; called by muse, mutect2, varscan2
- SP140 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59454238; called by muse, mutect2, varscan2
- SPECC1L | c.1142G>T p.R381L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV58658058, COSV58661368; called by mutect2, varscan2
- SPEM1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV57209784; called by muse, mutect2, varscan2
- SPTA1 | c.5531G>T p.R1844L | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs371114338, COSV63750532; called by muse, mutect2, varscan2
- SPTA1 | c.4257G>T p.R1419S | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV63758185; called by muse, mutect2, varscan2
- SRPK2 | c.1187A>T p.Q396L | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV61963710; called by muse, mutect2, varscan2
- STXBP5L | c.1616T>C p.I539T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as COSV56531520; called by muse, mutect2, varscan2
- SULT1B1 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV60209181; called by muse, mutect2, varscan2
- SYNE1 | c.26154G>A p.R8718= (on ENST00000367255 / NM_182961.4; = p.R8670= on NM_033071.3) | Splice Region (SNP) | VAF 14/116 reads (12%) | catalogued as rs1226539151, COSV55079652; called by muse, mutect2, varscan2
- SYT10 | c.1500G>C p.E500D | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV57344604; called by muse, mutect2, varscan2
- TBRG4 | c.1553A>G p.Y518C | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51834194; called by muse, mutect2
- TET2 | c.2512A>G p.T838A | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs377071504, COSV54429650; called by muse, mutect2, varscan2
- TIAM2 | c.2134C>A p.L712I | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59701928; called by muse, mutect2, varscan2
- TMEFF2 | c.838C>A p.H280N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.268); catalogued as COSV55839188; called by muse, mutect2, varscan2
- TMEM155 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100530086; called by muse, mutect2, varscan2
- TMEM200A | c.124C>A p.R42S | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV51658297; called by muse, mutect2
- TNIK | c.1257G>T p.Q419H | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV52693488; called by muse, mutect2, varscan2
- TPD52L3 | c.317G>T p.C106F | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV100096162; called by muse, mutect2, varscan2
- TPTE | c.1405G>T p.G469C (on ENST00000618007 / NM_199261.4; = p.G451C on NM_199259.4) | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs763153044; called by muse, mutect2, varscan2
- TRIB3 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53932442; called by muse, mutect2, varscan2
- TRIM58 | c.1109A>G p.K370R | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as COSV63571997; called by muse, mutect2, varscan2
- TSHZ1 | c.1638G>T p.K546N (on ENST00000580243 / NM_001308210.2; = p.K501N on NM_005786.6) | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV59010928, COSV59015813; called by muse, mutect2
- TTC30B | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 57/217 reads (26%) | catalogued as rs1162610780, COSV68809773; called by muse, mutect2, varscan2
- TTN | c.84247G>A p.E28083K (on ENST00000591111; = p.E20659K on NM_003319.4) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | PolyPhen benign (0.033); catalogued as rs370918981, COSV60279260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TWNK | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61328654; called by muse, mutect2, varscan2
- UGT2B11 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV71424236; called by mutect2, varscan2
- UGT2B15 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 136/658 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.06); catalogued as COSV57735622; called by muse, mutect2, varscan2
- UNC45B | c.1087T>C p.Y363H | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52099959; called by muse, mutect2
- USH2A | c.8785G>T p.A2929S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.047); catalogued as COSV56423565; called by muse, mutect2, varscan2
- VAV3 | c.784C>A p.Q262K | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV58390716; called by muse, mutect2
- VEPH1 | c.854A>T p.Y285F | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.196); catalogued as COSV62881964; called by muse, mutect2, varscan2
- VPS13A | c.8325G>A p.K2775= | Splice Region (SNP) | VAF 9/43 reads (21%) | catalogued as rs764150864, COSV62437333; called by muse, mutect2
- WDR1 | c.43G>C p.V15L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV101221157; called by muse, mutect2, varscan2
- WDR81 | c.3172G>T p.A1058S (on ENST00000409644 / NM_001163809.2; = p.A7S on NM_152348.4) | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100489234; called by muse, mutect2, varscan2
- ZFHX3 | c.7557G>T p.Q2519H | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.365); catalogued as COSV51732530; called by muse, mutect2, varscan2
- ZFP57 | c.1208A>T p.Q403L | Missense Mutation (SNP) | VAF 118/394 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV65306868; called by muse, mutect2, varscan2
- ZFYVE28 | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52116385, COSV99343538; called by muse, mutect2, varscan2
- ZNF132 | c.1322A>G p.N441S | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99571362; called by muse, mutect2, varscan2
- ZNF354C | c.916G>C p.G306R | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59609599; called by muse, mutect2, varscan2
- ZNF536 | c.2857G>T p.D953Y | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV62824207; called by muse, mutect2
- ZNF554 | c.984G>T p.Q328H | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV57886808; called by muse, mutect2, varscan2
- ZNF681 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV101267429, COSV101267591; called by muse, mutect2, varscan2
- ZNF772 | c.828C>A p.S276R | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV58410461, COSV58411606; called by muse, mutect2, varscan2
- ZNF804A | c.2089A>T p.T697S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV56467673; called by muse, mutect2, varscan2
- ZNFX1 | c.3647G>T p.R1216L | Missense Mutation (SNP) | VAF 73/191 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65601201; called by muse, mutect2, varscan2
- CCN6 | c.321dup p.R108* | Frame Shift Ins (INS) | VAF 11/102 reads (11%) | called by mutect2, varscan2
- CSMD3 | c.7394_7395del p.S2465Yfs*11 (on ENST00000297405 / NM_001363185.1; = p.S2361Yfs*11 on NM_052900.3) | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel, varscan2
- HYDIN | c.2521G>T p.A841S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by mutect2, varscan2
- IGHV3-66 | c.105del p.S36Pfs*2 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, varscan2
- KLHL31 | c.80dup p.N28Kfs*17 | Frame Shift Ins (INS) | VAF 5/48 reads (10%) | called by mutect2, pindel, varscan2
- MARS1 | c.1224_1225del p.C408Wfs*3 | Frame Shift Del (DEL) | VAF 12/111 reads (11%) | called by pindel, varscan2
- MYL2 | c.372del p.T125Rfs*22 | Frame Shift Del (DEL) | VAF 13/115 reads (11%) | called by mutect2, pindel, varscan2
- MYL9 | c.215del p.G72Afs*2 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- NFIB | c.539dup p.L180Ffs*20 | Frame Shift Ins (INS) | VAF 34/152 reads (22%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.432A>C p.R144S | Missense Mutation (SNP) | VAF 111/1163 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- PRAMEF18 | c.269C>A p.A90D | Missense Mutation (SNP) | VAF 60/729 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2
- PTGER4 | c.1458dup p.C487Mfs*50 | Frame Shift Ins (INS) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- SAMD9L | c.461del p.G154Vfs*3 | Frame Shift Del (DEL) | VAF 23/143 reads (16%) | called by mutect2, pindel, varscan2
- SYT6 | c.909del p.Y304Mfs*24 (on ENST00000610222 / NM_001366225.1; = p.Y219Mfs*24 on NM_205848.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/88 reads (24%) | called by mutect2, pindel, varscan2
- ZNF195 | c.568del p.E190Kfs*3 (on ENST00000399602 / NM_001130520.3; = p.E118Kfs*3 on NM_007152.5) | Frame Shift Del (DEL) | VAF 17/107 reads (16%) | called by pindel, varscan2
- ZNF273 | c.203_219del p.D68Gfs*9 | Frame Shift Del (DEL) | VAF 22/192 reads (11%) | called by mutect2, pindel
- AADACL3 | c.660G>T p.L220= | Silent (SNP) | VAF 42/203 reads (21%) | catalogued as rs1337468473, COSV60198526, COSV60199573; called by muse, mutect2, varscan2
- ABCA12 | c.3516C>A p.T1172= (on ENST00000272895 / NM_173076.3; = p.T854= on NM_015657.3) | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV55972883; called by muse, mutect2, varscan2
- ADAMTS18 | c.3600G>A p.Q1200= | Silent (SNP) | VAF 13/146 reads (9%) | catalogued as COSV51421973; called by muse, mutect2
- ADGRA2 | c.1548G>T p.V516= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV59446105; called by muse, mutect2, varscan2
- ANKEF1 | c.588G>T p.G196= | Silent (SNP) | VAF 33/180 reads (18%) | catalogued as rs1476201331, COSV65693481; called by muse, mutect2, varscan2
- ANKIB1 | c.1185A>C p.V395= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV56065363; called by mutect2, varscan2
- ANO1 | c.229C>A p.R77= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100304472; called by muse, mutect2, varscan2
- ARHGAP24 | c.1443G>T p.T481= (on ENST00000395184 / NM_001025616.3; = p.T388= on NM_031305.3) | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV51989818, COSV51990950; called by muse, mutect2, varscan2
- ASAH2 | c.912G>T p.P304= | Silent (SNP) | VAF 44/170 reads (26%) | called by muse, mutect2, varscan2
- ATRN | c.792T>C p.N264= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV53532983; called by muse, mutect2
- BEST1 | c.825C>A p.V275= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV57121567, COSV57122418; called by muse, mutect2, varscan2
- BMP10 | c.1173C>A p.P391= | Silent (SNP) | VAF 21/205 reads (10%) | catalogued as COSV54896791; called by muse, mutect2, varscan2
- BTBD10 | c.882C>G p.L294= | Silent (SNP) | VAF 39/147 reads (27%) | catalogued as COSV53401047; called by muse, mutect2, varscan2
- C11orf58 | c.54A>T p.P18= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99930396; called by muse, mutect2, varscan2
- C5 | c.4182C>T p.Y1394= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as rs142157475; called by muse, mutect2, varscan2
- CA11 | c.201G>A p.R67= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV50034060; called by muse, mutect2
- CACNA1E | c.3714T>A p.A1238= | Silent (SNP) | VAF 93/255 reads (36%) | catalogued as COSV62414738; called by muse, mutect2, varscan2
- CCDC102B | c.561T>C p.Y187= | Silent (SNP) | VAF 75/218 reads (34%) | catalogued as rs887363269, COSV60152300; called by muse, mutect2, varscan2
- CDH18 | c.771C>G p.T257= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV56954750; called by muse, mutect2, varscan2
- CDH9 | c.489A>G p.L163= | Silent (SNP) | VAF 32/147 reads (22%) | catalogued as COSV50408611; called by muse, mutect2, varscan2
- CEMIP | c.2655C>A p.I885= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as COSV54999172; called by muse, mutect2, varscan2
- CHD7 | c.2112C>T p.D704= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV71113891; called by muse, mutect2, varscan2
- COL15A1 | c.3444G>T p.A1148= | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as rs146027381, COSV66648538; called by muse, mutect2, varscan2
- CRISPLD1 | c.666G>T p.R222= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100082454; called by muse, mutect2, varscan2
- CTAGE1 | c.2145T>A p.A715= | Silent (SNP) | VAF 45/140 reads (32%) | catalogued as COSV66944510; called by muse, mutect2, varscan2
- CUBN | c.5982G>T p.P1994= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV64716353, COSV64727785; called by muse, mutect2, varscan2
- DNAAF4 | c.1110A>T p.V370= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV58251206; called by muse, mutect2, varscan2
- DNTTIP2 | c.1908A>G p.E636= | Silent (SNP) | VAF 29/185 reads (16%) | catalogued as COSV63284508; called by muse, mutect2, varscan2
- DTWD1 | c.201C>T p.F67= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV99233783; called by muse, mutect2, varscan2
- DYSF | c.4021C>T p.L1341= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV50500181, COSV50543820; called by muse, mutect2, varscan2
- ECRG4 | c.210G>T p.R70= | Silent (SNP) | VAF 35/153 reads (23%) | catalogued as COSV53001742; called by muse, mutect2, varscan2
- EXT1 | c.51C>T p.L17= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV65475585, COSV65484039; called by muse, mutect2, varscan2
- FLRT2 | c.840G>T p.R280= | Silent (SNP) | VAF 70/361 reads (19%) | catalogued as COSV58137371, COSV58148799; called by muse, mutect2, varscan2
- FOXB2 | c.831C>A p.G277= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1180003745, COSV100942396; called by muse, mutect2, varscan2
- GABPB2 | c.900A>C p.V300= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV64461453; called by muse, mutect2, varscan2
- GPATCH1 | c.1603C>T p.L535= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV50124214; called by muse, mutect2, varscan2
- HAUS6 | c.1605A>G p.K535= | Silent (SNP) | VAF 43/145 reads (30%) | catalogued as rs1372676754, COSV65840719; called by muse, mutect2, varscan2
- HSD17B4 | c.1215C>T p.I405= (on ENST00000414835 / NM_001199291.3; = p.I380= on NM_000414.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 56/187 reads (30%) | catalogued as COSV56338720; called by muse, mutect2, varscan2
- IGFL1 | c.180C>T p.V60= | Silent (SNP) | VAF 38/174 reads (22%) | catalogued as rs928143999, COSV71443680; called by muse, mutect2, varscan2
- IGHD4-11 | c.2G>A p.*1= | Silent (SNP) | VAF 51/191 reads (27%) | called by muse, mutect2, varscan2
- IMPG1 | c.1710C>A p.G570= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV64061045; called by muse, mutect2, varscan2
- IP6K2 | c.978C>T p.F326= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV53663238; called by muse, mutect2, varscan2
- ITPKA | c.1023C>T p.S341= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs770693606, COSV53027159, COSV99541181; called by muse, mutect2, varscan2
- KANK4 | c.2844C>A p.L948= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100443338; called by muse, mutect2, varscan2
- KCNA4 | c.1260C>T p.G420= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs200158908; called by muse, mutect2, varscan2
- KIF3C | c.1119G>A p.E373= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV53101397; called by muse, mutect2, varscan2
- LAMB1 | c.72C>A p.P24= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV55969397; called by muse, mutect2
- LILRA1 | c.1026G>T p.V342= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV52184273; called by muse, mutect2, varscan2
- LILRB5 | c.471G>A p.E157= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV60260519; called by muse, mutect2, varscan2
- LPL | c.135C>A p.T45= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as COSV60932613; called by muse, mutect2, varscan2
- LRFN2 | c.228G>T p.T76= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100599940; called by muse, mutect2, varscan2
- LRP1 | c.12477C>G p.L4159= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs201583024, COSV54523612; called by muse, mutect2
- LRP1B | c.7359C>A p.I2453= | Silent (SNP) | VAF 51/166 reads (31%) | catalogued as COSV67265506; called by muse, mutect2, varscan2
- MAP7D3 | c.2595C>T p.D865= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV60172285; called by muse, mutect2, varscan2
- MED7 | c.534A>G p.S178= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99644323; called by muse, mutect2, varscan2
- MIA3 | c.360G>T p.T120= | Silent (SNP) | VAF 34/292 reads (12%) | catalogued as COSV60515754, COSV60516917; called by muse, mutect2, varscan2
- MN1 | c.3033G>T p.G1011= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100180150; called by muse, mutect2
- MPPED1 | c.438C>T p.I146= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs369069551; called by muse, mutect2, varscan2
- MST1R | c.1803G>T p.L601= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV56573013; called by muse, mutect2, varscan2
- MYH8 | c.4483C>T p.L1495= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV67971143; called by muse, mutect2, varscan2
- NEURL4 | c.1005G>A p.K335= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV59762682; called by muse, mutect2, varscan2
- NPBWR1 | c.99G>A p.P33= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100488305; called by muse, mutect2, varscan2
- OR12D2 | c.753T>C p.Y251= | Silent (SNP) | VAF 28/238 reads (12%) | catalogued as rs778977218, COSV65829943; called by muse, mutect2, varscan2
- OR1A1 | c.726C>A p.S242= | Silent (SNP) | VAF 51/172 reads (30%) | catalogued as COSV100410812, COSV58404037; called by muse, mutect2, varscan2
- OR56A4 | c.366C>G p.S122= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV100417690; called by muse, mutect2, varscan2
- OR5B12 | c.75C>G p.L25= | Silent (SNP) | VAF 43/180 reads (24%) | catalogued as COSV56906463; called by muse, mutect2, varscan2
- OR5D16 | c.645C>A p.I215= | Silent (SNP) | VAF 34/143 reads (24%) | catalogued as COSV65722775; called by muse, mutect2, varscan2
- OR7E24 | c.225C>A p.T75= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs1028898501, COSV71702338; called by muse, mutect2, varscan2
- PCDH11Y | c.2172C>A p.G724= (on ENST00000400457 / NM_032973.2; = p.G713= on NM_032971.3) | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV53089624; called by muse, mutect2, varscan2
- PHKB | c.888G>T p.L296= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV54531999; called by muse, mutect2, varscan2
- PHLPP2 | c.1014A>C p.P338= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV62426920; called by muse, mutect2, varscan2
- PKDREJ | c.3826C>A p.R1276= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV53552425; called by muse, mutect2, varscan2
- PLEKHG6 | c.1551G>A p.E517= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV50610350; called by muse, mutect2
- PLXNA3 | c.1095G>T p.L365= | Silent (SNP) | VAF 175/237 reads (74%) | catalogued as COSV63755392; called by muse, mutect2, varscan2
- PNMA8A | c.1170G>A p.K390= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs1353018662, COSV100562432; called by muse, mutect2
- PSMA8 | c.33C>A p.V11= | Silent (SNP) | VAF 37/162 reads (23%) | catalogued as COSV57604728; called by muse, mutect2, varscan2
- RBFA | c.729G>T p.A243= | Silent (SNP) | VAF 49/154 reads (32%) | catalogued as COSV51534231, COSV51534990; called by muse, mutect2, varscan2
- RBMXL2 | c.885A>T p.G295= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs964630567, COSV100182557; called by muse, mutect2, varscan2
- RBP3 | c.1200G>T p.A400= | Silent (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- RIOK2 | c.1236T>C p.S412= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV51614880; called by muse, mutect2, varscan2
- RYR2 | c.5019C>A p.A1673= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV63709117; called by muse, mutect2, varscan2
- S1PR1 | c.846C>T p.C282= | Silent (SNP) | VAF 53/250 reads (21%) | catalogued as COSV59514401; called by muse, mutect2, varscan2
- SEMA5B | c.1131C>A p.T377= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV52106540; called by muse, mutect2, varscan2
- SEMA6C | c.1368A>G p.P456= | Silent (SNP) | VAF 20/157 reads (13%) | catalogued as COSV59007028; called by muse, mutect2, varscan2
- SHROOM4 | c.3571C>T p.L1191= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV56796049; called by muse, mutect2, varscan2
- SLC35F4 | c.519A>T p.S173= (on ENST00000339762 / NM_001352015.2; = p.S137= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV60266790; called by muse, mutect2, varscan2
- SPATA31A1 | c.3723C>A p.A1241= | Silent (SNP) | VAF 55/222 reads (25%) | called by mutect2, varscan2
- TACR3 | c.786C>T p.I262= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as rs747663025, COSV59207518; called by muse, mutect2, varscan2
- TMPO | c.825T>A p.I275= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV58463460; called by muse, mutect2, varscan2
- TOR1A | c.105C>T p.T35= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100693994; called by muse, mutect2, varscan2
- TUBGCP2 | c.928C>T p.L310= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV53308302; called by muse, mutect2, varscan2
- UBQLN1 | c.1161C>T p.N387= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1163070563, COSV57409171; called by muse, mutect2, varscan2
- WEE2 | c.1608G>A p.G536= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV66879949; called by muse, mutect2, varscan2
- XIRP2 | c.6345A>C p.P2115= (on ENST00000628543; = p.P2290= on NM_152381.6) | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV54729211; called by muse, mutect2, varscan2
- ZFPM2 | c.3117A>T p.R1039= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV65875512; called by muse, mutect2, varscan2
- ZP4 | c.1551C>A p.I517= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as COSV63911904, COSV63913250; called by muse, mutect2, varscan2
- AGAP7P | n.1677C>A | RNA (SNP) | VAF 108/283 reads (38%) | catalogued as rs200774242; called by muse, mutect2, varscan2
- C8orf31 | n.455G>A | RNA (SNP) | VAF 8/58 reads (14%) | catalogued as rs749760901; called by muse, mutect2, varscan2
- CTSL3P | n.322C>A | RNA (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- DSC3 | c.2494-102G>T | Intron (SNP) | VAF 25/79 reads (32%) | catalogued as COSV100844736; called by muse, mutect2, varscan2
- DST | c.4297-2228G>T | Intron (SNP) | VAF 23/162 reads (14%) | catalogued as rs140152012, COSV99760005; called by muse, mutect2, varscan2
- MASP1 | c.1303+4986G>T | Intron (SNP) | VAF 22/113 reads (19%) | catalogued as COSV99962846; called by muse, mutect2, varscan2
- NBPF25P | n.1831G>C | RNA (SNP) | VAF 33/196 reads (17%) | called by muse, mutect2, varscan2
- PIK3CD | c.-138+2585G>A | Intron (SNP) | VAF 19/87 reads (22%) | catalogued as rs773335772, COSV66098793, COSV66098845; called by muse, mutect2, varscan2
- PKD1L2 | chr16:81137452 G>A | 5'Flank (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- R3HDML | chr20:44355831 G>C | 3'Flank (SNP) | VAF 4/35 reads (11%) | catalogued as COSV53837558; called by muse, mutect2
- SSPOP | n.4100G>T | RNA (SNP) | VAF 18/59 reads (31%) | catalogued as COSV50489090; called by muse, mutect2, varscan2
- ZNF271P | n.1046G>T | RNA (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
